CCDI case PBCUZT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/6aae5212-d205-489d-820a-e6e1139ebd1a

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E0AR2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0ARB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
